Somatic mutation profile of tumor specimen ALCH-ABD2-TTP1-A (aliquot ALCH-ABD2-TTP1-A-1-0-D-A485-36) from ALCHEMIST case ALCH-ABD2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Lepidic predominant adenocarcinoma; Age at diagnosis: 62.9 years (22,972 days).
Specimen ALCH-ABD2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9108ae5-37be-4807-a354-4017580fe526.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABD2-NB1-A (Blood Derived Normal), aliquot ALCH-ABD2-NB1-A-1-0-D-A485-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4771405-7c4b-4dc1-ba8e-4886b1d1a75c

The open-access MAF lists 55 somatic variants for this specimen: 41 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Intron 6, Silent 6, Nonsense Mutation 3, Frame Shift Ins 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 94/555 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- CACNA1B | c.3520C>T p.R1174C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs201771536, COSV104374615; called by muse, mutect2, varscan2
- CAMSAP1 | c.3038A>T p.E1013V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as rs760564669; called by muse, mutect2, varscan2
- CD151 | c.497A>T p.D166V | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV58990604; called by muse, mutect2, varscan2
- CFAP94 | c.910G>A p.E304K (on ENST00000320267 / NM_001352064.2; = p.E310K on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.596); catalogued as COSV57229895, COSV57231301; called by muse, varscan2
- DDX51 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs764461438, COSV57959106; called by muse, mutect2, varscan2
- EPHB1 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs542190087, COSV101213019; called by muse, mutect2, varscan2
- GPR52 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.131); catalogued as rs767839389; called by muse, mutect2, varscan2
- HBEGF | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs1270676962, COSV50183118; called by muse, mutect2, varscan2
- MAGEE1 | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs782637952; called by muse, mutect2, varscan2
- PLCE1 | c.589A>C p.M197L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1185188574; called by muse, mutect2, varscan2
- PRG4 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 71/619 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs142813803; called by muse, mutect2, varscan2
- RAB3C | c.508T>C p.F170L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.835); catalogued as rs1229884837; called by muse, mutect2, varscan2
- RTL1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as rs781748333, COSV66017612; called by muse, mutect2, varscan2
- SLC22A3 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 68/409 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs537020286, COSV51710586; called by muse, mutect2, varscan2
- SLC25A47 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 23/175 reads (13%) | catalogued as rs762777320; called by muse, mutect2, varscan2
- TCHP | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 51/437 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs766568517; called by muse, mutect2, varscan2
- ABI3 | c.625T>A p.F209I | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMN1 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | called by muse, varscan2
- BHLHE22 | c.1039T>C p.Y347H | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2
- DOCK6 | c.1868T>G p.L623R | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DSG2 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); called by muse, varscan2
- EML5 | c.2705A>T p.H902L | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ESYT3 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- FAM20C | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 56/393 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- GLIS2 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HOOK3 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP19-7 | c.133A>T p.R45* | Nonsense Mutation (SNP) | VAF 67/248 reads (27%) | called by muse, mutect2, varscan2
- LTA4H | c.833_834dup p.V279Lfs*2 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, pindel
- P2RX7 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRKD1 | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- RAD54L2 | c.3073C>G p.P1025A | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- RNF212 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SV2B | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- TENM4 | c.1135A>T p.M379L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIM68 | c.171T>G p.C57W | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTC27 | c.1528_1529dup p.D511Efs*38 | Frame Shift Ins (INS) | VAF 50/428 reads (12%) | called by mutect2, pindel, varscan2
- TTN | c.88441G>A p.V29481I (on ENST00000591111; = p.V22057I on NM_003319.4) | Missense Mutation (SNP) | VAF 28/181 reads (15%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TUBD1 | c.1246A>G p.M416V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- VCPIP1 | c.2329A>T p.I777F | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF154 | c.1132G>T p.V378F | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- IGLV8-61 | c.177C>G p.P59= | Silent (SNP) | VAF 21/295 reads (7%) | called by muse, mutect2
- IMMT | c.30G>A p.V10= | Silent (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
- LEMD2 | c.279C>T p.A93= | Silent (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- MUC16 | c.20304G>A p.A6768= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs868841083; called by muse, mutect2, varscan2
- NRSN1 | c.585C>G p.T195= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV101027172; called by muse, mutect2, varscan2
- POLR3A | c.3591C>G p.P1197= | Silent (SNP) | VAF 18/416 reads (4%) | called by muse, mutect2
- FMN1 | c.2044-1825A>T | Intron (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- ICA1L | c.1244-692G>C | Intron (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- IL1RN | c.205+27T>A | Intron (SNP) | VAF 26/244 reads (11%) | called by muse, mutect2, varscan2
- MCM7 | chr7:100101861 G>C | 5'Flank (SNP) | VAF 84/702 reads (12%) | called by muse, mutect2, varscan2
- RBMS2 | c.543-878C>T | Intron (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- SATL1 | c.-532T>C | 5'UTR (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- TPD52L2 | c.477-3160C>G | Intron (SNP) | VAF 22/474 reads (5%) | catalogued as COSV53861254; called by muse, mutect2
- VAV3 | c.2351-2234C>A | Intron (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2
